Somatic mutation profile of tumor specimen TCGA-UZ-A9Q1-01A (aliquot TCGA-UZ-A9Q1-01A-11D-A42J-10) from TCGA case TCGA-UZ-A9Q1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I.
Specimen TCGA-UZ-A9Q1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 874ba810-b8f3-4e38-be41-eb229616cabe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UZ-A9Q1-10A (Blood Derived Normal), aliquot TCGA-UZ-A9Q1-10A-01D-A42M-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c743e761-319f-4b8d-8b1c-1bfa59d857e6

The open-access MAF lists 91 somatic variants for this specimen: 64 protein-altering or splice-affecting, 26 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 46, Silent 26, Frame Shift Ins 5, Nonsense Mutation 4, In Frame Del 3, Frame Shift Del 3, Splice Site 2, 5'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.81T>A p.Y27* | Nonsense Mutation (SNP) | VAF 50/60 reads (83%) | hotspot (GDC flag); catalogued as CM128488, COSV64291164, COSV64310374; called by muse, mutect2, varscan2
- ANPEP | c.2085G>T p.W695C | Missense Mutation (SNP) | VAF 65/135 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100263303; called by muse, mutect2, varscan2
- ANPEP | c.554A>G p.E185G | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100263305; called by muse, mutect2, varscan2
- ARID5A | c.1183C>A p.R395S | Missense Mutation (SNP) | VAF 62/152 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs776386275, COSV100673623; called by muse, mutect2, varscan2
- ATP7A | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 109/273 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.03); catalogued as COSV58441707; called by muse, mutect2, varscan2
- AVEN | c.437G>T p.S146I | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV100145632; called by muse, varscan2
- BIVM-ERCC5 | c.151G>A p.G51S | Missense Mutation (SNP) | VAF 73/183 reads (40%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.439); catalogued as COSV99958939; called by muse, mutect2, varscan2
- CCR9 | c.653A>T p.K218M (on ENST00000357632 / NM_031200.3; = p.K206M on NM_006641.4) | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100591735; called by muse, mutect2, varscan2
- CD209 | c.509A>T p.Y170F | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.153); catalogued as COSV99214200; called by muse, mutect2, varscan2
- CEP135 | c.52C>T p.Q18* | Nonsense Mutation (SNP) | VAF 163/440 reads (37%) | catalogued as COSV99954693; called by muse, mutect2, varscan2
- CEP43 | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 110/265 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs1203334820, COSV100835682; called by muse, mutect2, varscan2
- CHEK2 | c.1417C>T p.H473Y (on ENST00000382580 / NM_001005735.2; = p.H430Y on NM_007194.4) | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as COSV100102110; called by muse, mutect2, varscan2
- CYC1 | c.628T>C p.Y210H | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100010511; called by muse, mutect2, varscan2
- CYP1B1 | c.1333T>C p.F445L | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148233007, CM082588; called by muse, mutect2, varscan2
- DPY19L1 | c.1957G>T p.D653Y | Missense Mutation (SNP) | VAF 114/447 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV100204840; called by muse, mutect2, varscan2
- DTX3L | c.2114A>T p.D705V | Missense Mutation (SNP) | VAF 92/157 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99950092; called by muse, mutect2, varscan2
- EEF1G | c.1027A>T p.T343S | Missense Mutation (SNP) | VAF 39/102 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV100240511; called by muse, mutect2, varscan2
- GFOD2 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs145155253; called by muse, mutect2, varscan2
- GPAT3 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 72/169 reads (43%) | catalogued as COSV100023144; called by muse, mutect2, varscan2
- GPR152 | c.1093C>G p.Q365E | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.173); catalogued as COSV100351593, COSV56885084; called by muse, mutect2, varscan2
- GSR | c.1540T>C p.S514P | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99645691; called by muse, mutect2, varscan2
- GYS1 | c.495C>T p.F165= | Splice Region (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99620937; called by muse, mutect2, varscan2
- HECTD1 | c.3438A>G p.I1146M | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.185); catalogued as COSV101237436; called by muse, mutect2, varscan2
- IL17B | c.154C>T p.R52W | Missense Mutation (SNP) | VAF 84/218 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs141618878, COSV55784600; called by muse, mutect2, varscan2
- KAZN | c.2111C>T p.T704M | Missense Mutation (SNP) | VAF 129/321 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.513); catalogued as rs1186087350, COSV100184505; called by muse, mutect2, varscan2
- KMT2C | c.11812+1G>A p.X3938_splice | Splice Site (SNP) | VAF 51/80 reads (64%) | catalogued as COSV51523460; called by muse, mutect2, varscan2
- MIGA2 | c.1546C>T p.Q516* | Nonsense Mutation (SNP) | VAF 15/55 reads (27%) | catalogued as rs1178688124, COSV99477641; called by muse, mutect2, varscan2
- NAV3 | c.4208C>T p.T1403M | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57066934; called by muse, mutect2
- NELFCD | c.1592A>T p.K531M (on ENST00000602795; = p.K513M on NM_198976.4) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV99413670; called by muse, mutect2, varscan2
- NUDT16L1 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.467); catalogued as rs1397694912, COSV99274525; called by muse, mutect2, varscan2
- NUP58 | c.792G>C p.E264D | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as COSV101098845; called by muse, mutect2, varscan2
- OR7A10 | c.533dup p.C179Lfs*2 | Frame Shift Ins (INS) | VAF 61/188 reads (32%) | catalogued as rs758596389; called by mutect2, pindel, varscan2
- PDZRN4 | c.1733A>T p.N578I (on ENST00000402685 / NM_001164595.2; = p.N320I on NM_013377.4) | Missense Mutation (SNP) | VAF 79/278 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.067); catalogued as COSV100115045; called by muse, mutect2, varscan2
- PIM3 | c.10T>C p.S4P | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100638434; called by muse, varscan2
- PPFIA3 | c.3310T>G p.F1104V | Missense Mutation (SNP) | VAF 64/161 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); catalogued as COSV99418135; called by muse, mutect2, varscan2
- RAI1 | c.2933A>T p.K978M | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as COSV99884592; called by muse, mutect2, varscan2
- RAPGEF1 | c.2368G>A p.V790M | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV100940671; called by muse, mutect2, varscan2
- RORB | c.1262T>A p.I421K (on ENST00000396204 / NM_001365023.1; = p.I410K on NM_006914.4) | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.421); catalogued as COSV100974401; called by muse, mutect2, varscan2
- RPL23A | c.193G>A p.A65T | Missense Mutation (SNP) | VAF 91/225 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.053); catalogued as rs756926665, COSV99411824; called by muse, mutect2, varscan2
- RXFP1 | c.2125G>T p.G709C | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.28); catalogued as COSV57054678; called by muse, mutect2, varscan2
- SGTB | c.91A>G p.S31G | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.144); catalogued as COSV101114389; called by muse, mutect2, varscan2
- SMG6 | c.3487A>G p.M1163V | Missense Mutation (SNP) | VAF 11/116 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as rs369806279; called by muse, mutect2, varscan2
- SPATA31D1 | c.3947G>A p.R1316H | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs771246167, COSV61200809; called by muse, mutect2, varscan2
- TMUB1 | c.92C>G p.T31R | Missense Mutation (SNP) | VAF 113/191 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.871); catalogued as COSV52539454, COSV99879861; called by muse, mutect2, varscan2
- TNRC6A | c.1018A>T p.N340Y | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.347); catalogued as COSV100170287; called by muse, mutect2, varscan2
- TSHZ2 | c.1550T>G p.L517W | Missense Mutation (SNP) | VAF 65/124 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100296462; called by muse, mutect2, varscan2
- TUT7 | c.2981C>A p.T994K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); catalogued as COSV99463323; called by muse, mutect2, varscan2
- VPS50 | c.322A>G p.I108V | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.833); catalogued as rs1224080069, COSV99298375; called by muse, mutect2, varscan2
- XPR1 | c.1774A>C p.I592L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.83); PolyPhen benign (0.006); catalogued as COSV100851493; called by muse, mutect2, varscan2
- ZBTB21 | c.2246T>C p.V749A | Missense Mutation (SNP) | VAF 36/75 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.81); catalogued as COSV100177244; called by muse, mutect2, varscan2
- ZFYVE16 | c.2753C>T p.S918F | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.005); catalogued as rs952702904, COSV100566544; called by muse, mutect2
- ZNF462 | c.6568G>C p.V2190L | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.37); PolyPhen benign (0.042); catalogued as COSV99472661; called by muse, mutect2, varscan2
- ACVR2A | c.1347+2del p.X449_splice | Splice Site (DEL) | VAF 20/73 reads (27%) | called by mutect2, pindel, varscan2
- ADAMTS7 | c.760dup p.M254Nfs*11 | Frame Shift Ins (INS) | VAF 31/81 reads (38%) | called by mutect2, pindel, varscan2
- ARHGAP32 | c.4678_4687dup p.S1563Ffs*49 (on ENST00000310343 / NM_001378025.1; = p.S1214Ffs*49 on NM_014715.4) | Frame Shift Ins (INS) | VAF 34/110 reads (31%) | called by mutect2, varscan2
- FNIP2 | c.424_426del p.M142del | In Frame Del (DEL) | VAF 56/142 reads (39%) | called by pindel, varscan2
- JHY | c.2187_2191del p.T730Sfs*20 | Frame Shift Del (DEL) | VAF 109/272 reads (40%) | called by mutect2, pindel, varscan2
- MMP28 | c.1091A>C p.E364A | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- P3H3 | c.2015_2030del p.W672Lfs*9 | Frame Shift Del (DEL) | VAF 22/90 reads (24%) | called by mutect2, pindel, varscan2
- PTH1R | c.150dup p.R51Tfs*32 | Frame Shift Ins (INS) | VAF 127/242 reads (52%) | called by mutect2, varscan2
- SEC24B | c.1813_1833del p.C605_Y611del | In Frame Del (DEL) | VAF 29/87 reads (33%) | called by mutect2, pindel, varscan2
- ST8SIA2 | c.413del p.N138Tfs*12 | Frame Shift Del (DEL) | VAF 50/165 reads (30%) | called by mutect2, pindel, varscan2
- STEAP4 | c.236_247del p.I79_H82del | In Frame Del (DEL) | VAF 26/134 reads (19%) | called by mutect2, varscan2
- ZNF597 | c.246dup p.A83Cfs*13 | Frame Shift Ins (INS) | VAF 54/114 reads (47%) | called by mutect2, varscan2
- ADAM17 | c.648T>C p.A216= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as rs900692737, COSV100176392; called by muse, mutect2, varscan2
- AEBP1 | c.1533C>A p.L511= | Silent (SNP) | VAF 74/127 reads (58%) | catalogued as COSV99788947; called by muse, mutect2, varscan2
- BOLL | c.165G>A p.Q55= | Silent (SNP) | VAF 30/75 reads (40%) | catalogued as COSV56572988; called by muse, mutect2, varscan2
- BRD4 | c.2793C>T p.Y931= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV99651085; called by muse, mutect2, varscan2
- CNKSR3 | c.1128T>G p.P376= | Silent (SNP) | VAF 46/112 reads (41%) | catalogued as COSV101401381; called by muse, mutect2, varscan2
- DMXL2 | c.4788C>T p.V1596= | Silent (SNP) | VAF 28/61 reads (46%) | catalogued as COSV51842950, COSV99196763; called by muse, mutect2, varscan2
- EPS8 | c.2319C>G p.V773= | Silent (SNP) | VAF 76/142 reads (54%) | catalogued as COSV99843433; called by muse, mutect2, varscan2
- FAM83G | c.849T>C p.N283= | Silent (SNP) | VAF 70/152 reads (46%) | catalogued as COSV100525321; called by muse, mutect2, varscan2
- GSDMD | c.1050T>A p.G350= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV99369504; called by muse, mutect2, varscan2
- HSPA8 | c.426T>C p.A142= | Silent (SNP) | VAF 19/35 reads (54%) | catalogued as rs1334520596, COSV99914508; called by muse, mutect2, varscan2
- IARS1 | c.1560C>T p.I520= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as rs1449290480, COSV100986844; called by muse, mutect2, varscan2
- KRT34 | c.15G>A p.K5= | Silent (SNP) | VAF 54/144 reads (38%) | catalogued as COSV101222686; called by muse, mutect2, varscan2
- MAGEB16 | c.723C>T p.F241= | Silent (SNP) | VAF 140/301 reads (47%) | catalogued as COSV101303318; called by muse, mutect2, varscan2
- MED17 | c.558G>A p.E186= | Silent (SNP) | VAF 42/94 reads (45%) | catalogued as COSV99316137; called by muse, mutect2, varscan2
- MRS2 | c.1113T>C p.H371= | Silent (SNP) | VAF 15/45 reads (33%) | catalogued as COSV99219048; called by muse, mutect2, varscan2
- MYO16 | c.351C>T p.V117= | Silent (SNP) | VAF 49/112 reads (44%) | catalogued as COSV99194201; called by muse, mutect2, varscan2
- OTP | c.597G>A p.L199= | Silent (SNP) | VAF 22/55 reads (40%) | catalogued as rs1346243108, COSV100119862; called by muse, mutect2, varscan2
- PTK6 | c.93G>A p.A31= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs370151198; called by muse, mutect2, varscan2
- PTPN12 | c.1527T>A p.T509= | Silent (SNP) | VAF 123/211 reads (58%) | catalogued as COSV99950540; called by muse, mutect2, varscan2
- RBBP8NL | c.153G>T p.R51= | Silent (SNP) | VAF 16/44 reads (36%) | catalogued as COSV99436806; called by muse, mutect2, varscan2
- RPS3A | c.151A>C p.R51= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV99923721; called by muse, mutect2, varscan2
- SBF2 | c.4149C>T p.F1383= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as COSV56311799; called by muse, mutect2, varscan2
- SLC7A7 | c.1530T>A p.S510= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV99591228; called by muse, mutect2, varscan2
- SORBS3 | c.1980C>T p.F660= | Silent (SNP) | VAF 44/107 reads (41%) | catalogued as rs752806921, COSV99531460; called by muse, mutect2, varscan2
- SYT2 | c.372G>C p.L124= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as COSV100937169; called by muse, mutect2, varscan2
- TARBP2 | c.859C>T p.L287= (on ENST00000266987 / NM_134323.2; = p.L266= on NM_004178.4) | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs1565902214, COSV99908589; called by muse, mutect2, varscan2
- PLEKHG5 | c.-28G>A | 5'UTR (SNP) | VAF 76/199 reads (38%) | catalogued as COSV100894856; called by muse, mutect2, varscan2
